Somatic mutation profile of tumor specimen 0DFA99 from CCDI case PBBRRI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 14.1 years (5,133 days).
Specimen 0DFA99: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 899012d1-4edd-4933-b17c-74d9bca8b05b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFA8Z (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/840065b8-f78f-4fe8-9a01-80c7bcd32140

The open-access MAF lists 70 somatic variants for this specimen: 47 protein-altering or splice-affecting, 9 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 9, Intron 9, Nonsense Mutation 2, 5'UTR 2, 3'UTR 2, Splice Region 2, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIAA0586 | c.3099G>A p.P1033= (on ENST00000619416 / NM_001244190.2; = p.P972= on NM_014749.5) | Splice Region (SNP) | VAF 127/309 reads (41%) | catalogued as rs540255320, CS158389, COSV54174204; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.181G>T p.D61Y | Missense Mutation (SNP) | VAF 167/589 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs397507510, CD055729, CM021127, CM101143, COSV61004841, COSV61006072, COSV61006164; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TNNT2 | c.824G>A p.R275Q (on ENST00000236918; = p.R272Q on NM_000364.4) | Missense Mutation (SNP) | VAF 236/528 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.233); catalogued as rs730881125, COSV52660825; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.542G>C p.R181P | Missense Mutation (SNP) | VAF 58/440 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as CM056067, CM920671, CM942120, COSV52675795, COSV52676870, COSV52730435, COSV53567603; called by muse, mutect2, varscan2
- BRD7 | c.1368del p.Y457Mfs*11 | Frame Shift Del (DEL) | VAF 122/583 reads (21%) | catalogued as COSV67158811; called by mutect2, varscan2
- CLDN18 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 126/350 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs138443095; called by muse, varscan2
- CYP11B1 | c.1174C>A p.L392I | Missense Mutation (SNP) | VAF 267/1091 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.817); catalogued as COSV99454331; called by mutect2, varscan2
- DSPP | c.1317C>A p.S439R | Missense Mutation (SNP) | VAF 140/741 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.917); catalogued as rs1171063709; called by muse, mutect2, varscan2
- FNDC1 | c.4847C>T p.T1616M | Missense Mutation (SNP) | VAF 77/287 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs371052938; called by muse, mutect2, varscan2
- LAMA5 | c.565G>T p.A189S | Missense Mutation (SNP) | VAF 116/598 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53362908; called by muse, mutect2, varscan2
- LIG1 | c.2393C>G p.T798S | Missense Mutation (SNP) | VAF 51/462 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as rs201184227; called by muse, mutect2, varscan2
- MICB | c.775G>T p.D259Y | Missense Mutation (SNP) | VAF 20/334 reads (6%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.999); catalogued as COSV52855567; called by muse, mutect2
- MORC2 | c.733G>A p.A245T (on ENST00000397641 / NM_001303256.3; = p.A183T on NM_014941.3) | Missense Mutation (SNP) | VAF 72/1267 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs771884588; called by muse, mutect2
- MYO19 | c.2327G>A p.R776Q (on ENST00000614623 / NM_001163735.1; = p.R576Q on NM_025109.5) | Missense Mutation (SNP) | VAF 187/447 reads (42%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs759876914; called by muse, mutect2, varscan2
- NDST3 | c.2421C>A p.F807L | Missense Mutation (SNP) | VAF 56/522 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56624526; called by mutect2, varscan2
- PAFAH1B1 | c.787G>T p.V263L | Missense Mutation (SNP) | VAF 149/415 reads (36%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV68210099; called by muse, mutect2, varscan2
- PGM5 | c.1120G>A p.G374R | Missense Mutation (SNP) | VAF 68/1097 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1488097345; called by muse, mutect2
- RNF139 | c.394G>C p.V132L | Missense Mutation (SNP) | VAF 513/1060 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as COSV52679416; called by muse, mutect2, varscan2
- SEZ6 | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 82/195 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as rs758671486; called by muse, mutect2, varscan2
- SLC12A5 | c.769G>A p.G257S (on ENST00000454036 / NM_001134771.2; = p.G234S on NM_020708.5) | Missense Mutation (SNP) | VAF 107/502 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs765343735, COSV54798288; called by muse, mutect2, varscan2
- TF | c.1089G>C p.W363C | Missense Mutation (SNP) | VAF 229/613 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53918362; called by muse, mutect2, varscan2
- TMEM132A | c.1438C>T p.R480C (on ENST00000453848 / NM_178031.3; = p.R481C on NM_017870.4) | Missense Mutation (SNP) | VAF 78/268 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs151003082; called by muse, mutect2, varscan2
- ZNF215 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 169/633 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs780015579, COSV53491912; called by muse, mutect2, varscan2
- ADAMTS3 | c.2245T>G p.S749A | Missense Mutation (SNP) | VAF 122/757 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CCER1 | c.630G>T p.Q210H | Missense Mutation (SNP) | VAF 229/596 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- DIO2 | c.581C>A p.A194E | Missense Mutation (SNP) | VAF 22/485 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EREG | c.200A>C p.K67T | Missense Mutation (SNP) | VAF 40/956 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.268); called by muse, mutect2
- FAM126A | c.153+6T>C | Splice Region (SNP) | VAF 38/698 reads (5%) | called by muse, mutect2
- LHX2 | c.1130C>A p.T377N | Missense Mutation (SNP) | VAF 42/546 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.441); called by muse, mutect2
- LMX1A | c.188C>G p.A63G | Missense Mutation (SNP) | VAF 50/600 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.272); called by muse, mutect2
- LRP1B | c.1170C>G p.Y390* | Nonsense Mutation (SNP) | VAF 74/944 reads (8%) | called by muse, mutect2
- NES | c.679C>T p.Q227* | Nonsense Mutation (SNP) | VAF 38/348 reads (11%) | called by muse, mutect2
- PHEX | c.2108A>G p.E703G | Missense Mutation (SNP) | VAF 24/240 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.446); called by mutect2, varscan2
- PIK3CG | c.2327A>T p.N776I | Missense Mutation (SNP) | VAF 148/880 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.056); called by muse, varscan2
- POP1 | c.475G>T p.A159S | Missense Mutation (SNP) | VAF 252/920 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- RETSAT | c.1380G>T p.M460I | Missense Mutation (SNP) | VAF 57/655 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- RFX2 | c.1747C>A p.Q583K | Missense Mutation (SNP) | VAF 125/456 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- SLC22A12 | c.1003G>T p.A335S | Missense Mutation (SNP) | VAF 157/554 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SMU1 | c.1427T>C p.L476P | Missense Mutation (SNP) | VAF 146/463 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TAS2R31 | c.495G>C p.K165N | Missense Mutation (SNP) | VAF 30/694 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.232); called by muse, mutect2
- THSD7A | c.2698C>A p.Q900K | Missense Mutation (SNP) | VAF 176/635 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- TIMELESS | c.1691C>A p.A564D | Missense Mutation (SNP) | VAF 93/775 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- TMC4 | c.399G>T p.E133D (on ENST00000617472 / NM_001145303.3; = p.E127D on NM_144686.4) | Missense Mutation (SNP) | VAF 51/767 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.029); called by muse, mutect2
- TRPC6 | c.1571A>G p.E524G | Missense Mutation (SNP) | VAF 471/970 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- U2SURP | c.386G>C p.G129A | Missense Mutation (SNP) | VAF 66/579 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- UGT2B10 | c.1525A>C p.K509Q | Missense Mutation (SNP) | VAF 98/892 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- ZNF837 | c.1569G>C p.K523N | Missense Mutation (SNP) | VAF 46/487 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.339); called by muse, mutect2
- ARHGAP35 | c.3528C>T p.S1176= | Silent (SNP) | VAF 23/161 reads (14%) | catalogued as rs1385907170, COSV68334655; called by muse, mutect2, varscan2
- CDKN2A | c.138G>A p.R46= | Silent (SNP) | VAF 66/297 reads (22%) | called by muse, mutect2, varscan2
- FAM149A | c.999C>T p.G333= (on ENST00000356371 / NM_001367768.2; = p.G42= on NM_015398.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 141/512 reads (28%) | catalogued as rs143432779; called by muse, mutect2, varscan2
- FIBCD1 | c.201C>G p.V67= | Silent (SNP) | VAF 71/235 reads (30%) | called by muse, mutect2, varscan2
- GPX1 | c.96G>C p.L32= | Silent (SNP) | VAF 46/374 reads (12%) | called by muse, mutect2, varscan2
- JPH3 | c.2049G>A p.L683= | Silent (SNP) | VAF 123/242 reads (51%) | catalogued as rs1322155062; called by muse, mutect2, varscan2
- PPP1R9A | c.1878C>T p.A626= | Silent (SNP) | VAF 69/649 reads (11%) | catalogued as rs771931593, COSV56898685; called by muse, mutect2, varscan2
- PZP | c.2964T>C p.P988= | Silent (SNP) | VAF 137/794 reads (17%) | called by muse, mutect2, varscan2
- SIX5 | c.1947G>A p.A649= | Silent (SNP) | VAF 58/616 reads (9%) | catalogued as rs751459007, COSV52178768; called by muse, mutect2
- AC005833.1 | c.*83A>T | 3'UTR (SNP) | VAF 6/60 reads (10%) | called by mutect2, varscan2
- CD9 | c.175+56C>A | Intron (SNP) | VAF 17/173 reads (10%) | called by muse, mutect2
- CYHR1 | c.246+1905G>T | Intron (SNP) | VAF 87/370 reads (24%) | called by muse, mutect2, varscan2
- DIO2 | c.223-2967C>A | Intron (SNP) | VAF 144/444 reads (32%) | called by muse, mutect2, varscan2
- ELAVL2 | c.-12-2787G>C | Intron (SNP) | VAF 133/370 reads (36%) | called by muse, mutect2, varscan2
- ISYNA1 | c.609+89C>T | Intron (SNP) | VAF 27/252 reads (11%) | called by muse, mutect2, varscan2
- MUCL3 | c.947-35C>T | Intron (SNP) | VAF 50/654 reads (8%) | called by muse, mutect2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 8/73 reads (11%) | called by muse, varscan2
- PELP1 | c.570+34C>G | Intron (SNP) | VAF 25/203 reads (12%) | called by muse, mutect2, varscan2
- R3HDM4 | c.227-81G>A | Intron (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
- SIPA1L2 | c.-14C>G | 5'UTR (SNP) | VAF 69/557 reads (12%) | catalogued as rs1436409768; called by muse, mutect2, varscan2
- SPX | c.-43G>A | 5'UTR (SNP) | VAF 46/571 reads (8%) | called by muse, mutect2
- TCHHL1 | chr1:152080705 G>A | 3'Flank (SNP) | VAF 248/599 reads (41%) | catalogued as rs759545399; called by muse, mutect2, varscan2
- VIPR1 | c.*11C>G | 3'UTR (SNP) | VAF 14/260 reads (5%) | called by muse, mutect2
